Somatic mutation profile of tumor specimen TCGA-2G-AAFE-01A (aliquot TCGA-2G-AAFE-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 37.9 years (13,845 days).
Specimen TCGA-2G-AAFE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c425cae-db19-4467-bf1b-76361d8ab8f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFE-10A (Blood Derived Normal), aliquot TCGA-2G-AAFE-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba533d07-f4ad-4fde-8be1-b7161a09f3ea

The open-access MAF lists 54 somatic variants for this specimen: 45 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 5, Splice Site 2, Intron 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 34/87 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMT | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs774408322; called by muse, mutect2, varscan2
- CABIN1 | c.6430T>C p.F2144L | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs1411629687; called by muse, mutect2, varscan2
- CCNB3 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52081209; called by muse, mutect2, varscan2
- DIAPH1 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV53883766; called by muse, mutect2, varscan2
- DPYSL5 | c.1272C>G p.F424L | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV56513020; called by muse, mutect2, varscan2
- LMOD3 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs762365035; called by muse, mutect2, varscan2
- MACF1 | c.21901+1G>T p.X7301_splice (on ENST00000372915; = p.X5346_splice on NM_012090.5) | Splice Site (SNP) | VAF 69/294 reads (23%) | catalogued as COSV57105411; called by muse, mutect2, varscan2
- PANK1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs766474519, COSV56807375; called by muse, mutect2, varscan2
- PPP6R1 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1370584658, COSV69799239; called by muse, mutect2, varscan2
- PXDNL | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV62494166; called by muse, mutect2, varscan2
- TTN | c.65381C>A p.T21794K (on ENST00000591111; = p.T14370K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | PolyPhen benign (0.344); catalogued as COSV59897768; called by muse, mutect2, varscan2
- TTN | c.58115T>G p.V19372G (on ENST00000591111; = p.V11948G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/147 reads (12%) | PolyPhen probably damaging (0.943); catalogued as COSV59917659; called by muse, mutect2, varscan2
- WRN | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs946559389; called by muse, mutect2, varscan2
- ZNF483 | c.2166C>G p.N722K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58517649; called by muse, mutect2, varscan2
- ABCA13 | c.3873del p.F1291Lfs*8 | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | called by pindel, varscan2
- ACE | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ACOT9 | c.286A>T p.S96C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ANKRD61 | c.1228T>A p.C410S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- BPIFB6 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BRPF1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- BRPF1 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- C1QTNF1 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CAMK2B | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CD180 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300E | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DICER1 | c.4291G>T p.A1431S | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DNAH17 | c.7228A>T p.T2410S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FCGBP | c.9763T>A p.C3255S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- FILIP1L | c.2035C>T p.H679Y (on ENST00000354552 / NM_182909.3; = p.H439Y on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FXYD6 | c.-5-3C>G | Splice Region (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- GABPA | c.992C>G p.T331S | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GNL3L | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA3 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL13 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NIPBL | c.5427+1G>T p.X1809_splice | Splice Site (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- OR4C6 | c.711_712del p.C238Qfs*? | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by muse*, mutect2, varscan2*
- POLR1A | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SAE1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC35G5 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST8SIA2 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 15/143 reads (10%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STAB1 | c.425T>C p.F142S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TUBB | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- USP5 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- VXN | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- C12orf45 | c.81G>A p.K27= | Silent (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- DMD | c.1689T>C p.R563= | Silent (SNP) | VAF 66/248 reads (27%) | called by muse, mutect2, varscan2
- HARS1 | c.213A>T p.A71= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- PHLPP1 | c.2112G>A p.G704= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs1374063121; called by muse, mutect2, varscan2
- SLC26A8 | c.507C>T p.N169= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs768681322; called by muse, mutect2, varscan2
- PLEKHG4 | c.3104-29C>T | Intron (SNP) | VAF 18/108 reads (17%) | catalogued as rs1201261127; called by muse, mutect2, varscan2
- SPAG11A | chr8:7863531 G>T | 3'Flank (SNP) | VAF 43/362 reads (12%) | catalogued as rs1246225812; called by muse, mutect2, varscan2
- ZNF638 | c.2378-2685_2378-2684del | Intron (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- ZNF672 | c.*272_*273del | 3'UTR (DEL) | VAF 13/112 reads (12%) | catalogued as rs1474572502; called by mutect2, pindel, varscan2
